Gene-level copy-number profile of tumor specimen TCGA-10-0926-01A from TCGA case TCGA-10-0926, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.8 years (23,307 days).
Specimen TCGA-10-0926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.7f20859a-904e-4a7b-b57b-20ad49c3eeae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-10-0926-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7d95067a-c003-4934-acd1-8ffb11021ce7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,778; copy number 2: 22,425; copy number 3: 25,512; copy number 4: 8,721; copy number 6: 649; copy number 7: 98; copy number 9: 54; copy number 11: 456; copy number 12: 24; copy number 13: 18; copy number 16: 39; copy number 18: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-10-0926-01A-01D-0399-01): tumor purity 0.87, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 731 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:564,296–29,784,759, 731 genes, copy number 7–18 (within-gene range 6–18) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
